Somatic mutation profile of tumor specimen TCGA-EJ-A7NK-01A (aliquot TCGA-EJ-A7NK-01A-12D-A34U-08) from TCGA case TCGA-EJ-A7NK, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.9 years (21,530 days).
Specimen TCGA-EJ-A7NK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9053c3d-2501-42b9-b8ea-aeaea8857cfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A7NK-10A (Blood Derived Normal), aliquot TCGA-EJ-A7NK-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/405d7351-2be1-4d90-9277-2b0a14088bab

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSRNP1 | c.780+1G>A p.X260_splice | Splice Site (SNP) | VAF 6/56 reads (11%) | catalogued as COSV56189389, COSV99826742; called by muse, mutect2
